CCDI case PBBUHJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4ce4249d-96ea-4f84-92be-8d5ba10b8724

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.6 years (3,515 days).

Biospecimens (3 samples)
- Sample 0DHMLT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHMNU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHMR5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
